Surgical pathology report (de-identified scan), TCGA case TCGA-R8-A6ML, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site MD Anderson, specimen TCGA-R8-A6ML-01A (Primary Tumor).

[page 1 of 2]
M

(174.0cm 85.0kg BSA: 2.03m²)

Accession:

Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) LEFT FRONTAL MASS -
ANAPLASTIC OLIGODENDROGLIOMA, GRADE III (WHO).
(B) LEFT FRONTAL MASS -

ANAPLASTIC OLIGODENDROGLIOMA, GRADE III (WHO). See comment.

Entire report and diagnosis completed by

COMMENT

There is early microvascular proliferation. Combined with areas of high cellularity and brisk mitotic activity, this is best considered an anaplastic (grade III) tumor.

GROSS DESCRIPTION

(A) LEFT FRONTAL MASS - The specimen consists of a single piece of cerebral cortex and underlying white matter measuring 5.0 x 5.0 x 4.0 cm. The cut surface shows a loss of demarcation of the gray-white junction and a 2.0 cm area of gray discoloration. Representative portions are submitted for frozen section and smear in cassettes A1 and A2, and additional representative sections are submitted in cassettes A3-A7.

*FS/DX: INFILTRATING GLIOMA.

(B) LEFT FRONTAL MASS - A piece of tan-white soft tissue, 2.2 x 1.5 x 0.5 cm. The specimen is bisected and entirely submitted in B1 and B2.

CLINICAL HISTORY

Left brain mass.

SNOMED CODES

T-A2000, M-94513

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Released by:

Start of ADDENDUM

ICD-0.3
Oligodendroglioma, anaplastic
9451/3
Site (C) Brain, supratentorial NOS
C71.0
JF 7/5/13

[page 2 of 2]
Accession:
Specimen Date/Time:

M

(174.0cm 85.0kg BSA: 2.03m²)

ADDENDUM

Florescence in situ hybridization was performed for markers on chromosomes 1p and 19q and shows loss at both chromosomal arms. Combined 1p/19q loss has been shown to correlate with the oligodendroglial lineage and may predict a more favorable response to adjuvant therapy compared with tumors showing intact 1p/19q.

Entire report and diagnosis completed by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 0a8270eb-fa89-4d67-8e29-78d27080b8c6 (TCGA-R8-A6ML.E87BD3AD-C060-4DF5-8396-0DE9A036C5EB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).